Somatic mutation profile of tumor specimen C3N-00559-01 (aliquot CPT0068610009) from CPTAC case C3N-00559, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IA; Tumor grade: G2; Age at diagnosis: 55.7 years (20,344 days).
Specimen C3N-00559-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0ee5c36b-4cdb-4436-a119-c765a4e48c46.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00559-71 (Blood Derived Normal), aliquot CPT0068730002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/998e42dc-34d4-4206-acb5-d73587eb7786

The open-access MAF lists 66 somatic variants for this specimen: 45 protein-altering or splice-affecting, 14 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 39, Silent 14, 3'UTR 3, Frame Shift Ins 2, RNA 2, 5'Flank 1, Nonsense Mutation 1, Intron 1, In Frame Del 1, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2235_2249del p.E746_A750del | In Frame Del (DEL) | VAF 661/1461 reads (45%) | hotspot (GDC flag); catalogued as rs121913421, COSV51765119; ClinVar: drug response; called by mutect2, pindel, varscan2
- TP53 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 357/864 reads (41%) | hotspot (GDC flag); SIFT tolerated (0.13); PolyPhen possibly damaging (0.643); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACSS3 | c.43G>A p.G15R | Missense Mutation (SNP) | VAF 20/511 reads (4%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.005); catalogued as rs979928609, COSV99698962; called by muse, mutect2
- COL4A3 | c.4678G>A p.V1560I | Missense Mutation (SNP) | VAF 30/326 reads (9%) | SIFT tolerated (0.25); PolyPhen benign (0.025); catalogued as rs574102153, COSV67414364; ClinVar: uncertain significance; called by muse, mutect2
- FAM189B | c.1754G>A p.R585Q | Missense Mutation (SNP) | VAF 57/688 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as rs756717030; called by muse, mutect2
- FCRL3 | c.1756G>A p.V586I | Missense Mutation (SNP) | VAF 47/684 reads (7%) | SIFT tolerated (0.24); PolyPhen benign (0.056); catalogued as rs145354138; called by muse, mutect2
- KAT6A | c.5639C>T p.S1880L | Missense Mutation (SNP) | VAF 45/390 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as rs201870299; called by muse, mutect2, varscan2
- KCNA1 | c.496G>A p.A166T | Missense Mutation (SNP) | VAF 18/336 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV101230293; called by muse, mutect2
- KIF1A | c.202G>A p.A68T | Missense Mutation (SNP) | VAF 54/712 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.843); catalogued as rs761950783; called by muse, mutect2
- NALCN | c.2291G>A p.R764H | Missense Mutation (SNP) | VAF 27/200 reads (14%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.927); catalogued as rs760331955, COSV99215559; called by muse, mutect2, varscan2
- NOTCH4 | c.4064G>A p.R1355Q | Missense Mutation (SNP) | VAF 17/354 reads (5%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as rs567483221, COSV66680533; called by muse, mutect2
- PRICKLE3 | c.1501C>T p.R501C | Missense Mutation (SNP) | VAF 55/546 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.924); catalogued as rs782039505; called by muse, mutect2, varscan2
- RNF213 | c.9628C>T p.H3210Y | Missense Mutation (SNP) | VAF 30/374 reads (8%) | SIFT tolerated (0.3); PolyPhen benign (0.046); catalogued as rs763363712; called by muse, mutect2
- SLC12A5 | c.2407C>T p.R803C (on ENST00000454036 / NM_001134771.2; = p.R780C on NM_020708.5) | Missense Mutation (SNP) | VAF 50/358 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.836); catalogued as rs757395459, COSV54788236; called by muse, mutect2
- SLCO2B1 | c.1288G>A p.V430I | Missense Mutation (SNP) | VAF 17/171 reads (10%) | SIFT tolerated (0.96); PolyPhen benign (0.007); catalogued as rs374986387; called by muse, mutect2, varscan2
- SPANXB1 | c.127C>T p.P43S | Missense Mutation (SNP) | VAF 42/498 reads (8%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.986); catalogued as rs1352933123; called by muse, mutect2
- THBS2 | c.2945G>A p.R982H | Missense Mutation (SNP) | VAF 67/237 reads (28%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); catalogued as rs1477536579; called by muse, mutect2, varscan2
- APOBR | c.2557A>G p.T853A (on ENST00000431282; = p.T862A on NM_018690.4) | Missense Mutation (SNP) | VAF 39/229 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ASPN | c.345G>C p.K115N | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.348); called by muse, varscan2
- CDH2 | c.31C>G p.L11V | Missense Mutation (SNP) | VAF 55/287 reads (19%) | SIFT tolerated (0.54); PolyPhen benign (0.364); called by muse, mutect2, varscan2
- DCAF8 | c.631G>A p.G211S | Missense Mutation (SNP) | VAF 25/794 reads (3%) | SIFT tolerated (0.38); PolyPhen benign (0.258); called by muse, mutect2
- DIO3 | c.616G>A p.G206S | Missense Mutation (SNP) | VAF 54/1196 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- DYNC1H1 | c.11309T>C p.L3770P | Missense Mutation (SNP) | VAF 206/706 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FAF2 | c.542A>G p.D181G | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.076); called by muse, mutect2
- FHOD1 | c.1909G>C p.A637P | Missense Mutation (SNP) | VAF 30/697 reads (4%) | SIFT tolerated (0.26); PolyPhen benign (0.027); called by muse, mutect2
- GPR135 | c.259C>G p.R87G | Missense Mutation (SNP) | VAF 87/393 reads (22%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- GTF3C1 | c.6238A>G p.M2080V | Missense Mutation (SNP) | VAF 115/671 reads (17%) | SIFT tolerated (0.56); PolyPhen benign (0); called by muse, mutect2, varscan2
- KAT6A | c.5193C>G p.I1731M | Missense Mutation (SNP) | VAF 44/375 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- L1CAM | c.1498G>T p.A500S | Missense Mutation (SNP) | VAF 74/1238 reads (6%) | SIFT tolerated (0.76); PolyPhen benign (0.006); called by muse, mutect2
- MCUR1 | c.127T>A p.S43T | Missense Mutation (SNP) | VAF 505/1203 reads (42%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0); called by mutect2, varscan2
- NAAA | c.499-1_499insTT p.I167Lfs*13 | Frame Shift Ins (INS) | VAF 3/32 reads (9%) | called by mutect2, pindel
- NR3C2 | c.1289A>T p.E430V | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.882); called by muse, mutect2, varscan2
- OGFOD1 | c.1520dup p.E508Rfs*10 | Frame Shift Ins (INS) | VAF 4/45 reads (9%) | called by mutect2, pindel
- OR4C3 | c.149G>T p.S50I | Missense Mutation (SNP) | VAF 10/109 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); called by muse, mutect2
- PPARGC1B | c.1303G>T p.E435* | Nonsense Mutation (SNP) | VAF 34/578 reads (6%) | called by muse, mutect2
- RCN1 | c.12_31del p.G5Vfs*40 | Frame Shift Del (DEL) | VAF 28/192 reads (15%) | called by mutect2, pindel
- SCN5A | c.4163A>G p.N1388S (on ENST00000333535 / NM_198056.3; = p.N1387S on NM_000335.5) | Missense Mutation (SNP) | VAF 91/246 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.163); called by muse, mutect2, varscan2
- SOX30 | c.1057C>A p.P353T | Missense Mutation (SNP) | VAF 13/216 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.793); called by muse, mutect2
- SPNS2 | c.1297G>A p.E433K | Missense Mutation (SNP) | VAF 32/550 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.781); called by muse, mutect2
- VEZT | c.2048C>T p.P683L | Missense Mutation (SNP) | VAF 14/111 reads (13%) | SIFT tolerated (0.45); PolyPhen benign (0); called by muse, mutect2, varscan2
- VEZT | c.2246C>T p.S749F | Missense Mutation (SNP) | VAF 46/204 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZFYVE21 | c.435-1G>C p.X145_splice | Splice Site (SNP) | VAF 71/282 reads (25%) | called by muse, mutect2, varscan2
- ZNF135 | c.635A>T p.K212I (on ENST00000313434 / NM_001289401.2; = p.K224I on NM_003436.4) | Missense Mutation (SNP) | VAF 62/215 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- ZNF189 | c.1376A>T p.D459V | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.312); called by muse, mutect2, varscan2
- ZNF282 | c.1593G>C p.K531N | Missense Mutation (SNP) | VAF 40/417 reads (10%) | SIFT tolerated (0.38); PolyPhen benign (0.09); called by muse, mutect2
- ALPI | c.1329G>A p.A443= | Silent (SNP) | VAF 79/297 reads (27%) | catalogued as COSV55013464; called by muse, mutect2, varscan2
- CLEC14A | c.51G>A p.G17= | Silent (SNP) | VAF 14/382 reads (4%) | called by muse, mutect2
- CSMD2 | c.7521C>G p.A2507= | Silent (SNP) | VAF 19/386 reads (5%) | called by muse, mutect2
- DUSP28 | c.9G>A p.P3= | Silent (SNP) | VAF 53/270 reads (20%) | catalogued as rs770039516; called by muse, mutect2, varscan2
- FLG | c.3438C>T p.H1146= | Silent (SNP) | VAF 126/1880 reads (7%) | catalogued as rs769215947; called by muse, mutect2
- HECW2 | c.609C>T p.F203= | Silent (SNP) | VAF 8/47 reads (17%) | called by muse, mutect2, varscan2
- MELTF | c.855C>T p.A285= | Silent (SNP) | VAF 62/873 reads (7%) | catalogued as rs1296525280; called by muse, mutect2
- MYH7 | c.714C>T p.N238= | Silent (SNP) | VAF 74/1485 reads (5%) | catalogued as rs202141819, COSV62519883; ClinVar: benign / likely benign / uncertain significance; called by muse, mutect2
- NEU4 | c.69C>T p.R23= (on ENST00000391969 / NM_001167602.3; = p.R35= on NM_080741.4) | Silent (SNP) | VAF 42/618 reads (7%) | catalogued as rs761194255; called by muse, mutect2
- PCDHA10 | c.144G>A p.A48= | Silent (SNP) | VAF 192/1159 reads (17%) | catalogued as rs782508103; called by muse, mutect2, varscan2
- PCDHB9 | c.1935G>A p.K645= | Silent (SNP) | VAF 54/1818 reads (3%) | called by muse, mutect2
- PLG | c.2034T>C p.T678= | Silent (SNP) | VAF 16/302 reads (5%) | called by muse, mutect2
- TMEM191B | c.532T>C p.L178= | Silent (SNP) | VAF 6/22 reads (27%) | called by mutect2, varscan2
- ZNF804B | c.2355C>T p.C785= | Silent (SNP) | VAF 14/49 reads (29%) | called by muse, mutect2, varscan2
- CDC14A | chr1:100351774 C>T | 5'Flank (SNP) | VAF 16/218 reads (7%) | called by muse, mutect2
- GDA | c.*12G>A | 3'UTR (SNP) | VAF 14/114 reads (12%) | catalogued as rs377713055; called by muse, mutect2, varscan2
- HPGD | c.*30_*31del | 3'UTR (DEL) | VAF 4/20 reads (20%) | called by mutect2, pindel
- OR2A13P | n.566C>G | RNA (SNP) | VAF 22/294 reads (7%) | catalogued as rs749235735; called by muse, mutect2
- PHACTR1 | c.664+2239del | Intron (DEL) | VAF 55/523 reads (11%) | called by mutect2, pindel
- SPATA31C2 | n.1847del | RNA (DEL) | VAF 84/442 reads (19%) | called by mutect2, varscan2
- XPO5 | c.*97T>C | 3'UTR (SNP) | VAF 55/473 reads (12%) | called by muse, mutect2, varscan2
